Surgical pathology report (de-identified scan), TCGA case TCGA-59-2354, project TCGA-OV (Ovarian Serous Cystadenocarcinoma), tissue source site Roswell Park, specimen TCGA-59-2354-01A (Primary Tumor).

[page 1 of 6]
SURGICAL PATHOLOGY REPORT

SPECIMEN(S):

- A. OMENTUM
- B. LT OVARIAN TUMOR AND TUBE
- C. CUL-DE-SAC TUMOR
- D. RT TUBE AND OVARY AND UTERUS
- E. LEFT PARAMETRIAL TUMOR
- F. ADDITIONAL CUL-DE-SAC TUMOR
- G. LEFT PELVIC NODES
- H. RIGHT PELVIC NODES
- I. OMENTUM AND TUMOR
- J. GASTRO COLIC LIGAMENT
- K. SPLEEN W/ GASTROCOLIC LIG TUMOR & SPLEENIC FLEXURE OF COLON
- L. APPENDIX W/ TUMOR

CLINICAL HISTORY:

PRE-OPERATIVE DIAGNOSIS:

Pelvic mass with ascites

INTRAOPERATIVE CONSULTATION DIAGNOSIS:

FSA: Omental tissue: Poorly differentiated carcinoma, favor serous type

FSB1, FSB2: Left ovarian tumor and left tube: Multilobulated cystic neoplasm with tumor infiltrating ovarian cortex. Final diagnosis deferred to permanent section.

Comment: FSB differential diagnosis includes primary peritoneal surface the carcinoma as other (R/O sex cord with germ cell/stromal tumor ? Brenner tumor components.

[page 2 of 6]
[REDACTED]

FSD: Right tube and ovary, tubes, tumor and bladder peritoneum: High grade carcinoma, favor serous surface carcinoma (involving uterine serosa and adnexal fibrovascular tissue).

Comment: tumor encases ovary (normal sized).

[REDACTED]

GROSS DESCRIPTION:

A. OMENTUM

Received fresh is a tan yellow piece of tan yellow firm adipose tissue measuring 4.0x3.5x1.0cm in greatest dimension. Representative section is submitted for frozen section in cassette FSA. 2 additional representative sections are submitted for permanent in 2 cassettes.

B. LEFT OVARIAN TUMOR AND TUBE

Received fresh for intraoperative consultation and frozen section is a left ovary with fallopian tube. The left fallopian tube measures 4cm in length and 0.4cm in diameter. The surface shows tan white tumor implant measuring up to 0.2cm in greatest dimension. The left ovary is 9.0x7.0x6.0cm and shows tan white smooth surface. Sectioning reveals a multilobulated cystic ovarian mass with tan white smooth lining and areas with a granular yellowish appearance. Sectioning throughout the specimen also shows areas of thickened walls with granular yellowish and solid appearance. The cyst contains tan white serous fluid. Representative sections of the specimen are submitted for frozen section in cassettes FSB1 and FSB2. Representative sections of the specimen are also submitted in permanent in cassettes B3-B9 as follows:

B3-B6: sections of solid and thickened cystic wall

B7-B8: sections of thin cystic wall

B9: sections of fallopian tube

C. CUL-DE-SAC TUMOR

Received fixed are multiple tan to white to gray, friable fragments of soft tissue measuring 6.0x4.0x2.5cm in aggregate. Representative sections of the specimen are submitted in 2 cassettes.

D. RIGHT TUBE AND OVARY WITH UTERUS AND TUMOR WITH BLADDER PERITONEUM

Received fresh for frozen section and intraoperative diagnosis is a uterus with attached right adnexa and portion of bladder peritoneum, weighing altogether 134gm. The surface of the uterus shows a 12x4x3.3cm in greatest dimension tumor mass encasing the right ovary and fallopian tube extending under broad ligament and bladder peritoneal reflection. Sectioning reveals that the tumor does not invade the right ovary grossly. The uterus measures 8.0cm in length, 5.0cm in width and 5.0cm anterior to posterior. The external surface shows small tan white tumor implants measuring up to 0.2cm in greatest dimension. The anterior wall of the tumor shows a subserosal fibroid. The endometrial cavity is lined by tan pink smooth unremarkable endometrium measuring 0.1cm in thickness. Sectioning throughout the myometrium shows no tumor invasion, however a 1.3cm in diameter, tan-white firm fibroid is identified in the posterior left aspect of the myometrium. Possible small tan white fibroids are also found scattered throughout the myometrium. The myometrial wall measures 2.0cm in thickness at the posterior wall and 3.3cm at the anterior wall. The ectocervix measures 2.5x2.0cm and shows tan pink smooth unremarkable mucosa. At the internal os is a dark brown bulging polyp is identified.

[REDACTED]

[page 3 of 6]
When opened, the endocervical canal shows a 2.0x1.0x0.9cm pedunculated polyp attached to the posterior wall of the endocervical canal. The right ovary measures 2.5x2.0x2.0cm. When sectioning, a 0.9cm in diameter cyst lined with a smooth white lining is identified. The surface of the ovary is also covered (as mentioned) with the tumor. The right fallopian tube measures 5.5x0.5cm and is also covered with the tumor. No gross invasion is identified to both the fallopian tube and the ovary. Representative sections of the specimen are submitted as follows:

- FSD: section of tumor and ovary
- D2-D3: posterior cervix with polyp
- D4: anterior cervix
- D5: posterior endometrium and myometrium full thickness
- D6-D7: full thickness of anterior endometrium and myometrium
- D8: right ovary
- D9: right ovary and tumor
- D10: tumor surrounding fallopian tube
- D11: more sections of tumor
- D12: section of tumor with peritoneal reflection
- D13: more sections of tumor

E. LEFT PARAMETRIAL TUMOR

Received fixed is a single tan brown irregular piece of tissue measuring 3.0x3.0x1.5cm in greatest dimension. The surface is irregular and granular. Sectioning reveals tan white solid tumor. Representative sections of the specimen are submitted in 1 cassette.

F. ADDITIONAL CUL-DE-SAC TUMOR

Received fixed are multiple tan yellow to brown fragments of tissue measuring 2.5x2.5x2.0cm in aggregate. Representative section of the specimen is submitted in 1 cassette.

G. LEFT PELVIC NODES

Received fixed is a single tan yellow piece of adipose tissue measuring 3.0x2.0x1.5cm in greatest dimension. Sectioning reveals multiple presumptive lymph nodes varying in size from 0.5 to 1.2cm in greatest dimension. All the lymph nodes are submitted as follows:

- G1: 2 presumptive lymph nodes
- G2: 1 bisected lymph node

H. RIGHT PELVIC NODES

Received fixed is a single tan yellow piece of adipose tissue measuring 2.0x1.0x1.0cm in greatest dimension. Specimen is bisected and submitted in toto in 1 cassette.

I. OMENTUM WITH TUMOR AND GASTROCOLIC LIGAMENT

Received fresh for tissue procurement is a single piece of tan yellow irregular firm adipose tissue measuring roughly 30x5x3cm in greatest dimension. Sectioning reveals tan white to yellow firm tissue. Representative sections are submitted in 2 cassettes.

J. GASTROCOLIC LIGAMENT TUMOR

Received fixed is a fragmented piece of tan brown irregular firm adipose tissue. Sectioning reveals tan white irregular firm tumor infiltrating the fat. Representative sections of the specimen are submitted in 1 cassette.

[page 4 of 6]
K. SPLEEN WITH GASTROCOLIC LIGAMENT TUMOR AND SPLENIC FLEXURE OF COLON

Received fixed are a spleen with attached adipose tissue and portion of splenic flexure of colon. The spleen measures 10x6x4cm and weighs 90gm. Sectioning reveals tumor invading the adipose tissue and the hilum and extending in through the spleen. It is difficult, however, to determine whether the spleen is invaded with the tumor grossly. The remainder of the spleen is grossly unremarkable. The attached portion of colon measures 27cm in length and 4.5cm in circumference and shows unremarkable mobile mucosa. Sectioning throughout the colonic wall in the area adjacent to the tumor shows no tumor invasion through the colonic wall grossly. In the minimal amount of attached pericolic adipose tissue, a single tan pink lymph node is identified measuring 0.5cm in diameter. Between the colon and the spleen and the gastrocolic ligament and soft tissue, a 9.0x6.0x6.0cm tan yellow firm tumor is identified. Also received is a tan yellow piece of adipose tissue representing omentum measuring 13x8x2.0cm in greatest dimension. Sectioning throughout the specimen shows 2 tumor nodules resembling the big tumor identified in the gastrocolic ligament. Representative sections of the specimen are submitted as follows:

K1-K2: section of spleen with adjacent possible tumor

K3: mid portion of colon in area adjacent to the tumor

K4: proximal margin

K5: distal margin

K6: pericolic lymph nodes

K7-K8: sections of tumor

K9-K10: representatives of the tumor nodules

L. APPENDIX WITH TUMOR

Received fixed is an appendix with attached mesoappendix measuring 5.5cm in length and 0.8cm in maximal diameter for the appendix. Attached mesoappendix measures 4.0x2.0x1.2cm in greatest dimension. Sectioning of the specimen shows tumor in the mesoappendix surrounding the appendix in the middle portion. Representative sections of the specimen are submitted as follows:

L1: appendiceal tip

L2-L3: section of tumor with appendix

L4: proximal margin of the appendix

DIAGNOSIS:

A. OMENTUM, BIOPSY:

- POORLY DIFFERENTIATED SEROUS CARCINOMA.

B. OVARIAN TUMOR AND TUBE, LEFT, SALPINGOOOPHORECTOMY:

- BRENNER TUMOR (2.2 CM DIAMETER).

- POORLY DIFFERENTIATED SEROUS CARCINOMA INVOLVING LYMPHOVASCULAR CHANNELS OF MESOSALPINX.

- FALLOPIAN TUBE NO TUMOR SEEN

[page 5 of 6]
C. CUL-DE-SAC TUMOR, EXCISION:

- POORLY DIFFERENTIATED SEROUS CARCINOMA.

D. UTERUS AND RIGHT TUBE AND OVARY, TAH/RIGHT SALPINGOOOPHORECTOMY:

- POORLY DIFFERENTIATED SEROUS CARCINOMA INVOLVING OVARIAN SURFACE, UTERINE SEROSA WITH INVASION OF EXTERNAL MYOMETRIUM WITH LYMPHATIC INVASION, AND MESOSALPINX
- UTERINE LEIOMYOMATA (HYALINIZED AND CALCIFIED),
- BENIGN BRENNER TUMOR (2.5 CM DIAMETER), RIGHT OVARY.
- BENIGN ENDOCERVICAL POLYP.

E. PARAMETRIAL TUMOR, LEFT, EXCISION:

- POORLY DIFFERENTIATED SEROUS CARCINOMA.

F. ADDITIONAL CUL-DE SAC TUMOR, EXCISION:

- POORLY DIFFERENTIATED SEROUS CARCINOMA.

G. LYMPH NODES, LEFT PELVIC, EXCISION:

- METASTATIC SEROUS CARCINOMA IN THREE OF THREE LYMPH NODES (3/3).

H. LYMPH NODES, RIGHT PELVIC, EXCISION:

- METASTATIC SEROUS CARCINOMA IN ONE OF ONE LYMPH NODE (1/1).

I. OMENTUM AND TUMOR, EXCISION:

- POORLY DIFFERENTIATED SEROUS CARCINOMA.

J. GASTROCOLIC LIGAMENT, EXCISION:

- POORLY DIFFERENTIATED SEROUS CARCINOMA.

K. SPLEEN WITH GASTROCOLIC LIGAMENT TUMOR AND SPLENIC FLEXURE OF COLON, EXCISION:

- POORLY DIFFERENTIATED SEROUS CARCINOMA INVOLVING BOWEL, SEROSA, MESENTERY, AND SPLENIC CAPSULE WITH EXTENSION INTO PERIPHERAL SPLENIC PARENCHYMA.
- BOWEL MARGINS NEGATIVE FOR TUMOR.

L. APPENDIX WITH TUMOR, APPENDECTOMY:

- POORLY DIFFERENTIATED SEROUS CARCINOMA INVOLVING APPENDICEAL SEROSA AND PERIAPPENDICEAL CONNECTIVE TISSUE.
-

[page 6 of 6]
[REDACTED]

NOTE: The histologic features present are most consistent with a primary peritoneal serous surface carcinoma which is poorly differentiated. Concurrent bilateral Brenner tumors of the ovary are present as well. [REDACTED] has reviewed the case and concurs. See template.

[REDACTED]

PERITONEUM TEMPLATE

Tumor Site: Omentum, right and left ovary, uterine serosa, parametrial tissue (left), lymph nodes, gastro colic ligament, spleen, and pericolic connective tissue, appendix serosa.

Organs Involved: Included bilateral ovaries, uterus, spleen, colon.

Size: NA

Histologic Type: Serous carcinoma

Histologic Grade: G3 - poorly differentiated

Angiolymphatic Invasion: Present

Additional Pathologic Findings: None

Lymph Nodes: Positive for four, with extranodal extension

NY ESO-1: Positive, focal (<5%) 3+

Comment: Case reviewed by [REDACTED] who concurs with this interpretation

[REDACTED]

Source: NCI Genomic Data Commons file 1b0c6e4b-eca5-4d4b-8e5c-375b7a0e78bc (TCGA-59-2354.CBDD4D6E-0DF4-4ABD-AF75-B3A66BDBA9CC.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).